Gene-level copy-number profile of tumor specimen TCGA-24-1464-01A from TCGA case TCGA-24-1464, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.8 years (25,874 days).
Specimen TCGA-24-1464-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f9aacc4e-2615-4434-a61b-664886f92289.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1464-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6d8aa76c-148c-4c02-8797-fe029e5961da

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 15,650; copy number 2: 35,219; copy number 3: 7,221; copy number 4: 1,004; copy number 5: 84; copy number 6: 224; copy number 7: 125; copy number 8: 50; copy number 9: 198.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1464-01A-01D-0472-01): tumor purity 0.85, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–738,106, 19 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1.
- chr8:738,548–893,112, 2 genes: AC100797.4, AC026950.2.
- chr17:31,008,497–31,575,659, 22 genes (within-gene range 0–1): AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724, MIR193A, AC003101.2, RNU6ATAC7P, AC003101.1, MIR4725, MIR365B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 681 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:88,326,836–88,887,573, 1 gene, copy number 5 (within-gene range 2–5): AC090578.1.
- chr8:88,808,318–101,169,629, 226 genes, copy number 5–7 (broad region; genes not listed).
- chr8:102,551,589–135,742,495, 413 genes, copy number 6–9 (broad region; genes not listed).
- chr8:135,977,329–135,980,588, 1 gene, copy number 6 (within-gene range 3–6): AC103955.1.
- chr12:120,740,470–121,107,490, 15 genes, copy number 5 (within-gene range 3–5): AC069234.1, SPPL3, ARF1P2, AC069214.1, CLIC1P1, RPL12P33, HNF1A-AS1, HNF1A, C12orf43, OASL, OASL2P, AC079602.2, AC079602.3, SNORA70, AC079602.1.
- chr14:55,229,217–56,310,761, 25 genes, copy number 5 (within-gene range 3–5): AL158801.4, COX5AP1, AL158801.2, FBXO34, AL158801.1, Metazoa_SRP, CHMP4BP1, AL158801.3, ATG14, HMGN1P1, TBPL2, RPL21P6, KTN1-AS1, RPL7AP4, ABI1P1, KTN1, Y_RNA, AL355773.1, RPL13AP3, LINC00520, AL163952.1, AL138995.1, PELI2, AL355073.1, AL355073.2.

Autosomal genes at a single copy (total copy number 1): 13,229. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
